MMRF case MMRF_1654 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/84d37b34-6a7e-4679-aa14-a53b4f20b956

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 86 years; Vital status: Dead; Days to death: 81 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 86.7 years (31,668 days); ISS stage: II; Days to last known disease status: 81 days; Days to last follow up: 81 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 81 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 50 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 81.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: M Protein 0.669 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40464 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 36.9 mg/dL; Immunoglobulin G 9.79 g/L; Immunoglobulin A 0.707 g/L; Immunoglobulin M 0.369 g/L; Beta 2 Microglobulin 3.95 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 318 ×10⁹/L; Creatinine 156 µmol/L; Calcium 2.1 mmol/L; Albumin 23 g/L; Total Protein 5.5 g/dL; Glucose 4.13 mmol/L.
- Day 64 (ECOG 4): Lactate Dehydrogenase 4.83 µkat/L; Hemoglobin 4.96 mmol/L; Leukocytes 12.8 ×10⁹/L; Absolute Neutrophil 8.69 ×10⁹/L; Platelets 526 ×10⁹/L; Creatinine 534 µmol/L; Calcium 2.75 mmol/L; Albumin 25 g/L; Total Protein 6.3 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day 0: Weight: 70 kg; Height: 156 cm.

Biospecimens (2 samples)
- Sample MMRF_1654_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1654_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
